Somatic mutation profile of tumor specimen MMRF_1674_1_BM_CD138pos (aliquot MMRF_1674_1_BM_CD138pos_T2_KBS5U_K11913) from MMRF case MMRF_1674, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.0 years (25,579 days).
Specimen MMRF_1674_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b87f3db0-38a1-4d69-a9a3-51c1543b8e1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1674_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1674_1_PB_Whole_C7_KBS5U_K11915; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84775778-e025-40e8-bf2c-017571d5f0dc

The open-access MAF lists 118 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 32, Intron 19, Silent 9, 3'Flank 4, 5'UTR 4, 5'Flank 4, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 50/108 reads (46%) | catalogued as rs372824554; called by muse, mutect2, varscan2
- ACP2 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs769811216; called by muse, mutect2, varscan2
- BARD1 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs753377280; called by muse, mutect2, varscan2
- CASR | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV56137066; called by muse, mutect2, varscan2
- DDX58 | c.709T>G p.L237V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1347809447; called by muse, mutect2, varscan2
- DRD3 | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55681902; called by muse, mutect2, varscan2
- IGLV3-1 | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1033441424; called by muse, mutect2, varscan2
- IGSF1 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200267796; called by muse, mutect2, varscan2
- KCNQ2 | c.1962G>T p.E654D (on ENST00000359125 / NM_172107.4; = p.E626D on NM_004518.6) | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV60540286; called by muse, mutect2, varscan2
- LAMC3 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs140139330; called by muse, mutect2, varscan2
- OR14A16 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV62927492, COSV62927571; called by muse, varscan2
- PPM1E | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs770018116, COSV57572508; called by muse, mutect2, varscan2
- PPP2R5A | c.202_204del p.Q68del | In Frame Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs771923439; called by pindel, varscan2
- RBM10 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 78/98 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61310218, COSV61310251; called by muse, mutect2, varscan2
- SH3GL2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs1563853926; called by muse, mutect2, varscan2
- SMDT1 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); catalogued as rs143143172; called by muse, mutect2, varscan2
- SP140 | c.2015dup p.R673Efs*9 | Frame Shift Ins (INS) | VAF 56/141 reads (40%) | catalogued as rs746109620; called by mutect2, varscan2
- ZNF202 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1032531266, COSV100279102; called by muse, mutect2, varscan2
- ZNF804B | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 116/247 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as rs1353055615; called by muse, mutect2, varscan2
- AGTR2 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 93/104 reads (89%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP6 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 77/86 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALR | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNC | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- CD109 | c.3911+2dup p.X1304_splice | Splice Site (INS) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- DIS3 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 68/77 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FKBP9 | c.565C>A p.R189S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- FRMD3 | c.930T>G p.Y310* | Nonsense Mutation (SNP) | VAF 74/165 reads (45%) | called by muse, mutect2, varscan2
- KRT32 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGED1 | c.202_208del p.S68Lfs*68 | Frame Shift Del (DEL) | VAF 58/69 reads (84%) | called by mutect2, pindel, varscan2
- MAPKAPK2 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 88/149 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MEPCE | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MKI67 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2
- OBP2A | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.275); called by mutect2, varscan2
- OR14A16 | c.247T>A p.S83T | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, varscan2
- OR51G2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PACRG | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PKHD1 | c.12085C>G p.Q4029E | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PLCE1 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- RASGRP2 | c.1420_1422dup p.C474dup | In Frame Ins (INS) | VAF 32/57 reads (56%) | called by mutect2, pindel, varscan2
- SPAG4 | c.224G>C p.S75T | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TIGD1 | c.176A>T p.K59M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TNXB | c.4942T>A p.S1648T (on ENST00000647633; = p.S1401T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZNF460 | c.1625T>C p.I542T | Missense Mutation (SNP) | VAF 105/192 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF610 | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ZPLD1 | c.1248A>G p.*416Wext*2 (on ENST00000466937 / NM_001329788.1; = p.*432Wext*2 on NM_175056.2) | Nonstop Mutation (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- C7 | c.2424G>A p.V808= | Silent (SNP) | VAF 65/139 reads (47%) | called by muse, mutect2, varscan2
- COL14A1 | c.648C>T p.S216= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs1488046769; called by muse, mutect2
- DDX3X | c.297A>G p.G99= (on ENST00000399959; = p.G100= on NM_001356.5) | Silent (SNP) | VAF 67/72 reads (93%) | called by muse, mutect2, varscan2
- FAT1 | c.1731A>C p.T577= | Silent (SNP) | VAF 75/154 reads (49%) | called by muse, mutect2, varscan2
- FAT4 | c.10791T>G p.S3597= | Silent (SNP) | VAF 79/160 reads (49%) | called by muse, mutect2, varscan2
- PLB1 | c.3915C>T p.F1305= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100578946, COSV59835495; called by muse, mutect2, varscan2
- SIPA1L2 | c.3492C>T p.D1164= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as rs764682648, COSV99476942; called by muse, mutect2, varscan2
- SLC29A3 | c.657C>T p.D219= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- TP63 | c.1110C>T p.N370= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs375593834; called by muse, mutect2, varscan2
- AC103993.1 | n.425T>A | RNA (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
- ACSL1 | c.993+99_993+100dup | Intron (INS) | VAF 30/61 reads (49%) | called by mutect2, varscan2
- ADCYAP1R1 | c.*2032T>C | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2905G>T | Intron (SNP) | VAF 29/35 reads (83%) | catalogued as rs1484352057; called by muse, mutect2, varscan2
- AUTS2 | c.*1338T>C | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- BMP6 | c.*1095_*1111delinsAAA | 3'UTR (DEL) | VAF 24/60 reads (40%) | called by pindel, varscan2*
- C11orf65 | c.*1193C>A | 3'UTR (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- CPXM2 | c.*500C>T | 3'UTR (SNP) | VAF 23/58 reads (40%) | catalogued as COSV53866069; called by muse, mutect2, varscan2
- CREB3L4 | c.174+39A>G | Intron (SNP) | VAF 67/106 reads (63%) | called by muse, mutect2, varscan2
- DDX20 | chr1:111755184 A>C | 5'Flank (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- DELE1 | chr5:141940607 C>T | 3'Flank (SNP) | VAF 104/208 reads (50%) | catalogued as rs560538178; called by muse, mutect2, varscan2
- DLG4 | chr17:7219404 del T | 5'Flank (DEL) | VAF 89/216 reads (41%) | called by mutect2, pindel, varscan2
- DUSP14 | c.*352T>G | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- EHMT1 | c.*421G>A | 3'UTR (SNP) | VAF 51/114 reads (45%) | called by muse, mutect2, varscan2
- F8 | c.*52C>T | 3'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- FAM20C | c.864-18530T>C | Intron (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- FAM20C | c.864-18529C>A | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- FAM20C | c.*400G>A | 3'UTR (SNP) | VAF 107/225 reads (48%) | catalogued as rs547861600; called by muse, mutect2, varscan2
- FCGR2B | c.392-61T>C | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- FGF1 | c.*971A>G | 3'UTR (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- FLT3LG | c.342+86G>T | Intron (SNP) | VAF 18/34 reads (53%) | catalogued as rs1454558985, COSV52621449; called by muse, mutect2, varscan2
- FOXG1 | chr14:28772676 C>A | 3'Flank (SNP) | VAF 79/169 reads (47%) | called by muse, mutect2, varscan2
- FRMD1 | chr6:168081364 G>A | 5'Flank (SNP) | VAF 30/35 reads (86%) | catalogued as rs990411075; called by muse, mutect2, varscan2
- GP2 | chr16:20309741 G>T | 3'Flank (SNP) | VAF 14/73 reads (19%) | catalogued as rs919538194; called by muse, mutect2
- GRIK4 | c.*426G>A | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- HOGA1 | c.*4C>T | 3'UTR (SNP) | VAF 56/114 reads (49%) | catalogued as rs372160388, COSV100167315; called by muse, mutect2, varscan2
- IFIT2 | c.*780C>G | 3'UTR (SNP) | VAF 8/106 reads (8%) | catalogued as rs1038435927; called by muse, mutect2
- INCENP | c.*948C>T | 3'UTR (SNP) | VAF 13/36 reads (36%) | catalogued as rs538618888; called by muse, mutect2, varscan2
- KRTAP8-1 | c.*174C>A | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- LANCL3 | c.*1074C>G | 3'UTR (SNP) | VAF 35/39 reads (90%) | called by muse, mutect2, varscan2
- LANCL3 | c.*1234T>G | 3'UTR (SNP) | VAF 29/31 reads (94%) | called by muse, mutect2, varscan2
- LTB | c.163-77C>G | Intron (SNP) | VAF 143/319 reads (45%) | catalogued as rs576331800, COSV53002587; called by muse, mutect2, varscan2
- LTB | c.162+136G>A | Intron (SNP) | VAF 41/71 reads (58%) | catalogued as rs541787102; called by muse, mutect2, varscan2
- MAD1L1 | c.1999-31871G>A | Intron (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- MAT2A | c.1085+277T>C | Intron (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*1643A>C | 3'UTR (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851315 C>T | 5'Flank (SNP) | VAF 87/159 reads (55%) | catalogued as rs537569481; called by muse, mutect2, varscan2
- NPR3 | c.-17C>G | 5'UTR (SNP) | VAF 124/276 reads (45%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+773A>G | Intron (SNP) | VAF 34/69 reads (49%) | catalogued as COSV55926447; called by muse, mutect2, varscan2
- NSD1 | c.*4503_*4521del | 3'UTR (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- NSD3 | c.2612-17_2612-16del | Intron (DEL) | VAF 46/165 reads (28%) | called by mutect2, pindel, varscan2
- PCYT2 | c.*2056C>G | 3'UTR (SNP) | VAF 24/65 reads (37%) | catalogued as rs752108362, COSV100325911; called by mutect2, varscan2
- PDE3A | c.1011+15370_1011+15373del | Intron (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- PINK1 | chr1:20651679 T>C | 3'Flank (SNP) | VAF 80/162 reads (49%) | called by muse, varscan2
- PITHD1 | c.-51C>T | 5'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as rs1221187655; called by muse, mutect2
- PRDM10 | c.*2015C>T | 3'UTR (SNP) | VAF 32/52 reads (62%) | called by muse, varscan2
- RASGRP2 | c.*6+76G>T | Intron (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- RBL1 | c.*2410del | 3'UTR (DEL) | VAF 28/50 reads (56%) | catalogued as rs889468519; called by mutect2, varscan2
- RIMS2 | c.*1603T>A | 3'UTR (SNP) | VAF 61/90 reads (68%) | called by muse, mutect2, varscan2
- ROBO2 | c.3554+243G>C | Intron (SNP) | VAF 55/111 reads (50%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*1296G>A | 3'UTR (SNP) | VAF 28/44 reads (64%) | called by muse, mutect2, varscan2
- SLC35B3 | c.-254A>C | 5'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- SLC49A4 | c.*1619G>A | 3'UTR (SNP) | VAF 31/55 reads (56%) | catalogued as rs543916524; called by muse, mutect2, varscan2
- SNX6 | c.429-732T>G | Intron (SNP) | VAF 96/223 reads (43%) | called by muse, mutect2, varscan2
- SPATA4 | c.*143T>C | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, varscan2
- TECPR2 | c.3932-17A>G | Intron (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- TMEM33 | c.*4686A>G | 3'UTR (SNP) | VAF 59/130 reads (45%) | called by muse, mutect2, varscan2
- TNRC6A | c.*1629A>C | 3'UTR (SNP) | VAF 60/99 reads (61%) | catalogued as rs1037302188; called by muse, mutect2, varscan2
- URGCP-MRPS24 | c.*389C>A | 3'UTR (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- VWA1 | c.*2138G>A | 3'UTR (SNP) | VAF 86/171 reads (50%) | called by muse, mutect2, varscan2
- WDR26 | c.*1873dup | 3'UTR (INS) | VAF 46/146 reads (32%) | called by mutect2, pindel, varscan2
- ZIC5 | c.*111G>A | 3'UTR (SNP) | VAF 33/38 reads (87%) | catalogued as rs951425053, COSV99940625; called by muse, mutect2, varscan2
- ZNF746 | c.520+3256G>C | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- ZSCAN22 | c.-46G>C | 5'UTR (SNP) | VAF 8/15 reads (53%) | catalogued as rs908023276; called by muse, mutect2, varscan2
